Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9ZR, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9ZR-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/21/23/14

- A. Anterior prostatic fat, biopsy: Benign vascular fibroadipose tissue, no tumor, no epithelium.
- B. Posterior bladder margin, biopsy: Prostatic adenocarcinoma, Gleason score 4+4=8, in fibroadipose tissue, nerve, ganglia and suspicious for lymphatic invasion.
- C. Posterior peritoneum, biopsy: Benign peritoneal tissue and fibroadipose tissue, no tumor.
- D. Right pelvic lymph nodes, dissection: Two benign lymph nodes, no tumor (0/2).
- E. Left pelvic lymph nodes, dissection: No tumor in five lymph nodes (0/5).
- F. Prostate gland, bilateral seminal vesicles, prostatectomy: Prostatic adenocarcinoma, Gleason score 5+4 = 9, with florid extraprostatic extension and bilateral seminal vesicle invasion, at three different inked resection margins; see comment.

COMMENT:

This case was amended on [REDACTED] to add results of additional tissue submitted for part D. At the request of the clinician, the remainder of parts D and E were submitted to evaluate for the presence of additional lymph nodes, and one additional lymph node without tumor was identified. This is now reflected in the gross description (all material of parts D and E now submitted, with additional blocks D2 and D3, and E2), and in the final diagnosis where an additional lymph node of part D is without tumor, and in the comment where total number of lymph nodes present is changed from 6 to 7. No other changes were made to this report.

The majority of the prostatic tissue (>85%) is involved by high-grade small acinar adenocarcinoma.

[page 2 of 4]
In TSS, no evidence in medical record of hormone deprivation therapy. B4

Only scant residual benign prostate is seen, and while all of this appears atrophic suggestive of preoperative hormone deprivation therapy, the tumor shows recognizable areas of Gleason patterns 3, 4 and 5 tumor, and therefore a grade is still reported. Three different margins have tumor at ink that are all in areas of extraprostatic extension; left anterior apex (at least 3mm, slides F4, F14), left posterior quadrant along posterior seminal vesicle (scattered microscopic foci, slides F13, F20), and right bladder resection margin (1mm slide F17). However, extensive cautery artifact precludes the grading of the carcinoma at these margins. In addition, tumor is present in adipose tissue and nerve of the separate specimen named "posterior bladder margin" (Slide B1), but no tumor is seen in the smooth (detrusor) muscle of this specimen. Extensive involvement of both the right and left seminal vesicles is also observed, as well as florid extraprostatic extension, the largest contiguous of such being at least 2cm (left Base).

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Throughout entire prostate, most extensive posteriorly, and on the left (right anterior base apparently contains less tumor).
- **Estimated volume of tumor:** As tumor is almost completely replacing (at least 85%) this 40 gram prostate, tumor volume is at least 30cc.
- **Gleason score:** 5+4; primary pattern 5, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** Greater than 90%.
- **Involvement of capsule:** Present, numerous areas.
- **Extraprostatic extension:** Present, extensive, multiple areas, largest contiguous area at least 2cm (left base).
- **Margin status for tumor:** Positive (at least 3mm left anterior apex, slides F4, F14; left posterior base, slides F13, F20 right bladder margin (slide F17). Gleason pattern at largest positive margin: Grading is precluded by extensive cautery artifact, but appears high grade (4 or 5).
- **Margin status for benign prostate glands:** None present.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; focally.
- **Tumor involvement of seminal vesicle:** Present; both sides.
- **Perineural infiltration:** Present, extensive.
- **Lymph node status:** Negative; total number of nodes examined: 7.
- **AJCC/UICC stage:** pT3bN0R1 (If the patient did receive adequate/appropriate neoadjuvant ADT course, the grade would be ypT3bN0R1; correlate with clinical history).

Specimen(s) Received

A:Anterior prostatic fat
B:Posterior bladder margin
C:Posterior peritoneum
D:Right pelvic LN
E:Left pelvic LN
F:Prostate & seminal vesicles (fresh)

Clinical History

The patient is a [redacted]-year-old man who per the electronic medical record [redacted] has a PSA of [redacted] who was found to have prostatic adenocarcinoma, Gleason 4 + 4 (see prior [redacted] report [redacted] . He now undergoes a robotic-assisted laparoscopic radical prostatectomy and bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in six parts, each labeled with the patient's name and medical record number. Parts A-E are all received in formalin. Part F is received fresh.

Part A is additionally labeled "anterior prostatic fat," and consists of two soft, irregular, unoriented, tan-yellow fibrofatty tissue fragments (4.5 x 3.7 x 0.6 cm in aggregate). No nodules or masses are palpated. Representative sections are submitted in cassette A1.

[page 3 of 4]
Part B is additionally labeled "posterior bladder margin," and consists of a single firm, unoriented, tan-white tissue fragment (1.3 x 1 x 0.4 cm). The specimen is entirely submitted in cassette B1.

Part C is additionally labeled "posterior peritoneum," and consists of a single soft, irregular, unoriented tan-white to yellow-brown tissue fragment (3.1 x 1.6 x 0.3 cm). One side is smooth, shiny and white-tan, while the opposite side is roughened and tan-brown. The roughened side is inked blue and the entire specimen is submitted in cassette C1.

Part D is additionally labeled "right pelvic lymph node," and consists of a single soft to firm, irregular, unoriented tan-yellow/brown fibrofatty tissue fragment (4.8 x 2.5 x 0.5 cm). A single candidate lymph node (3.3 cm in greatest dimension) is round and submitted in cassette D1. The remainder of the tissue is entirely submitted in cassettes D2 and D3.

Part E is additionally labeled "left pelvic lymph node," and consists of three soft to firm, irregular, unoriented, tan-yellow fibrofatty tissue fragments (3.2 x 1.7 x 0.7 cm in aggregate). Four candidate lymph nodes (0.5 - 2.7 cm in greatest dimension) are found and submitted in cassette E1. The remaining tissue is entirely submitted in cassette E2.

Part F is additionally labeled "prostate and seminal vesicles," and consists of a radical prostatectomy specimen (39.5 gm; 4 cm from apex to base x 4 cm in width x 3.5 cm from anterior to posterior). GROSS PATHOLOGIC FINDINGS: Making up approximately 85% of the prostate is a tan-yellow, firm, rubbery area (4 x 3.3 x 2 cm). It extends from the left posterior apex and spreads into both the left and right sides, stopping 0.2 cm from the bladder margin. The anterior fibrous stroma is red, roughened and is opened. The remaining capsule is intact. The remaining prostatic parenchyma is tan.

The seminal vesicle/vas deferens bundles (right 3.5 x 1.5 x 1 cm; left 3 x 1.5 x 1 cm) are soft, lobulated, red-tan without obvious lesion or mass. Some of the prostate is taken by the

ORIENTED BY: Anatomic landmarks, seminal vesicles, urethra.

INKING: - Right anterior: Green.- Left anterior: Blue.- Posterior: Black.

TOTAL NUMBER OF SLICES: Six; not including apex and base margin slices.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

F1: Right apex.

F2: Left apex.

Right half:

F3: Slice 1.

Left half:

F4: Slice 1.

Right anterior quadrant

F5: Slice 2.

F6: Slice 4.

F7: Slice 6.

Right posterior quadrant

F8: Slice 2.

F9: Slice 4.

F10: Slice 6.

Left posterior quadrant

F11: Slice 2.

F12: Slice 4.

F13: Slice 6.

Left anterior quadrant

F14: Slice 2.

F15: Slice 4.

F16: Slice 6.

Bladder margins, entirely submitted in perpendicular sections

[page 4 of 4]
F17: Right.
F18: Left.
Prostatic/seminal vesicle junction and cross-section of vas deferens
F19: Right.
F20: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed out on

Source: NCI Genomic Data Commons file 2fb0f614-f64d-4f9c-ba5e-94db3fe73b52 (TCGA-V1-A9ZR.DB23EC5B-D86A-4B32-8C52-E91CAD4B7695.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).